Somatic mutation profile of tumor specimen C3L-08154-01 (aliquot CPT0511550014) from CPTAC case C3L-08154, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G4; Age at diagnosis: 67.6 years (24,681 days).
Specimen C3L-08154-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bda95513-10cf-49cf-85b7-c29f2016e5b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08154-31 (Blood Derived Normal), aliquot CPT0511540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bd20484-88df-4709-bbc2-45da6455f18d

The open-access MAF lists 61 somatic variants for this specimen: 47 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 11, Nonsense Mutation 2, 3'UTR 1, Splice Site 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGFG2 | c.53G>C p.G18A | Missense Mutation (SNP) | VAF 132/1660 reads (8%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.098); catalogued as COSV99499581; called by muse, mutect2
- DACT3 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 94/1522 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1280729174; called by muse, mutect2
- DOCK3 | c.1655A>G p.E552G | Missense Mutation (SNP) | VAF 16/460 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99808613; called by muse, mutect2
- ERCC3 | c.1853C>A p.P618Q | Missense Mutation (SNP) | VAF 29/540 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53425672; called by muse, mutect2
- FIGLA | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 64/2154 reads (3%) | SIFT tolerated (0.46); PolyPhen benign (0.06); catalogued as rs782387486; called by muse, mutect2
- FZD10 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 90/1169 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57474837; called by muse, mutect2
- GALNT14 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 50/824 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61103846; called by muse, mutect2
- GALNT15 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 80/1102 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as rs140109953; called by muse, mutect2
- GPR83 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 35/706 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); catalogued as rs201742760; called by muse, mutect2
- GRK1 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 58/958 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs1238355634, COSV59552545; called by muse, mutect2
- HSPA2 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 82/1283 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1291087508; called by muse, mutect2
- LRRC32 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 54/1289 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs201431152; called by muse, mutect2
- MCAM | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 40/750 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs374860225; called by muse, mutect2
- MDC1 | c.5177C>A p.A1726D | Missense Mutation (SNP) | VAF 84/1487 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV64524405; called by muse, mutect2
- MUC16 | c.21772A>C p.S7258R | Missense Mutation (SNP) | VAF 52/742 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.93); catalogued as COSV101202346, COSV67479267; called by muse, mutect2
- OR2M5 | c.196C>A p.L66M | Missense Mutation (SNP) | VAF 39/810 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV63547101; called by muse, mutect2
- PCDHGB3 | c.1953G>C p.Q651H | Missense Mutation (SNP) | VAF 41/1178 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53934916; called by muse, mutect2
- PLEC | c.2575G>A p.A859T (on ENST00000322810 / NM_201380.4; = p.A749T on NM_000445.5) | Missense Mutation (SNP) | VAF 30/581 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372281911; called by muse, mutect2
- ROBO1 | c.3614C>T p.S1205F | Missense Mutation (SNP) | VAF 20/396 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as COSV71393042; called by muse, mutect2
- USH2A | c.10867T>A p.Y3623N | Missense Mutation (SNP) | VAF 26/638 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1410073; called by muse, mutect2
- ZFHX4 | c.2338A>T p.R780W | Missense Mutation (SNP) | VAF 46/614 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV50636918; called by muse, mutect2
- ZNF777 | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 108/2058 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.454); catalogued as COSV56097011; called by muse, mutect2
- AC136428.1 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 43/1057 reads (4%) | called by muse, mutect2
- CDRT1 | c.251A>T p.D84V | Missense Mutation (SNP) | VAF 23/398 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CELSR2 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 50/954 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAAF1 | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 82/680 reads (12%) | called by muse, varscan2
- EDRF1 | c.2751C>G p.H917Q (on ENST00000356792 / NM_001202438.2; = p.H883Q on NM_015608.2) | Missense Mutation (SNP) | VAF 68/769 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FAM174A | c.146G>T p.R49I | Missense Mutation (SNP) | VAF 80/1644 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); called by muse, mutect2
- FLG | c.3971A>G p.D1324G | Missense Mutation (SNP) | VAF 43/1138 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.632); called by muse, mutect2
- FXR1 | c.1822G>C p.E608Q | Missense Mutation (SNP) | VAF 15/291 reads (5%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.013); called by muse, mutect2
- IGHV3OR15-7 | c.50T>G p.V17G | Missense Mutation (SNP) | VAF 40/854 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- INO80B | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 62/1082 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2
- INVS | c.15G>C p.E5D | Missense Mutation (SNP) | VAF 14/472 reads (3%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.104); called by muse, mutect2
- KRTAP6-1 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 38/1266 reads (3%) | PolyPhen probably damaging (0.993); called by muse, mutect2
- MAGI1 | c.2995+1G>A p.X999_splice (on ENST00000402939 / NM_001033057.2; = p.X1027_splice on NM_004742.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 28/640 reads (4%) | called by muse, mutect2
- MCM7 | c.1142G>A p.G381E | Missense Mutation (SNP) | VAF 49/793 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MDC1 | c.5176G>A p.A1726T | Missense Mutation (SNP) | VAF 80/1474 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.077); called by muse, mutect2
- MYCL | c.131C>G p.P44R (on ENST00000372816 / NM_001033081.3; = p.P74R on NM_005376.5) | Missense Mutation (SNP) | VAF 106/1564 reads (7%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.856); called by muse, mutect2
- NPIPB15 | c.175A>G p.N59D | Missense Mutation (SNP) | VAF 49/834 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.681); called by muse, mutect2
- NRIP1 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 46/918 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NTRK2 | c.2168A>G p.E723G (on ENST00000323115 / NM_001369534.1; = p.E739G on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/970 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR5AS1 | c.866T>G p.I289S | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PCDHA1 | c.758A>G p.E253G | Missense Mutation (SNP) | VAF 36/587 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PIWIL1 | c.1076A>T p.Q359L | Missense Mutation (SNP) | VAF 48/1314 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- THBS3 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 22/858 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- TRIM23 | c.38T>C p.V13A | Missense Mutation (SNP) | VAF 55/1007 reads (5%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2
- ZBTB7A | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 43/1287 reads (3%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.017); called by muse, mutect2
- CAPN14 | c.63G>A p.A21= | Silent (SNP) | VAF 55/1028 reads (5%) | catalogued as rs768792436, COSV67290894; called by muse, mutect2
- CDH20 | c.1797C>T p.D599= | Silent (SNP) | VAF 61/1266 reads (5%) | catalogued as rs566748256; called by muse, mutect2
- CDK16 | c.1476G>C p.V492= | Silent (SNP) | VAF 56/611 reads (9%) | called by muse, mutect2
- DLL3 | c.975C>G p.G325= | Silent (SNP) | VAF 44/1035 reads (4%) | called by muse, mutect2
- HOXD10 | c.390G>A p.S130= | Silent (SNP) | VAF 32/648 reads (5%) | catalogued as rs1029196107, COSV50899217; called by muse, mutect2
- NKX1-1 | c.864G>C p.G288= | Silent (SNP) | VAF 114/1850 reads (6%) | called by muse, mutect2
- REPIN1 | c.639G>T p.G213= | Silent (SNP) | VAF 102/1938 reads (5%) | called by muse, mutect2
- RIMS1 | c.384C>T p.C128= | Silent (SNP) | VAF 34/731 reads (5%) | catalogued as rs914659964, COSV53462888; called by muse, mutect2
- SPIRE2 | c.816C>T p.T272= | Silent (SNP) | VAF 84/1394 reads (6%) | catalogued as rs760462525; called by muse, mutect2
- UBAP2L | c.1977G>A p.T659= | Silent (SNP) | VAF 46/726 reads (6%) | catalogued as rs778593165; called by muse, mutect2
- ZFP69B | c.210C>T p.S70= | Silent (SNP) | VAF 23/572 reads (4%) | catalogued as COSV64315948; called by muse, mutect2
- LINC00630 | n.473A>C | RNA (SNP) | VAF 29/168 reads (17%) | called by muse, mutect2, varscan2
- REG3A | c.*65A>C | 3'UTR (SNP) | VAF 30/689 reads (4%) | called by muse, mutect2
- SCUBE1 | c.727+2685G>A | Intron (SNP) | VAF 45/1084 reads (4%) | catalogued as rs1455140119; called by muse, mutect2
